Somatic mutation profile of tumor specimen TCGA-39-5024-01A (aliquot TCGA-39-5024-01A-21D-1817-08) from TCGA case TCGA-39-5024, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.6 years (23,975 days).
Specimen TCGA-39-5024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98237f41-ce91-4d81-936e-42d1bf364bc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5024-11A (Solid Tissue Normal), aliquot TCGA-39-5024-11A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebc0a252-95c2-4339-ad8e-c1863bdd1468

The open-access MAF lists 222 somatic variants for this specimen: 160 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 55, Nonsense Mutation 10, Splice Site 6, Intron 3, Frame Shift Del 3, 5'UTR 1, 3'Flank 1, IGR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 49/148 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-2A>T p.X307_splice | Splice Site (SNP) | VAF 17/67 reads (25%) | hotspot (GDC flag); catalogued as COSV52693974, COSV52706655, COSV52945558, COSV53066011; called by muse, mutect2, varscan2
- ABCA13 | c.13324G>A p.A4442T | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV68949277; called by muse, mutect2, varscan2
- ACSBG1 | c.895-1G>C p.X299_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV51908859; called by muse, mutect2, varscan2
- ADCY7 | c.2621C>T p.S874F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54269210; called by muse, varscan2
- APOB | c.9583G>C p.E3195Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV51945081; called by muse, mutect2, varscan2
- ARFGAP2 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576771926, COSV53567380; called by muse, mutect2
- ASTN1 | c.2059A>C p.I687L | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV56077798; called by muse, mutect2
- ATP13A2 | c.3068C>T p.T1023I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58702371; called by muse, mutect2, varscan2
- ATXN3 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61496800; called by muse, mutect2
- AVL9 | c.1528G>C p.A510P | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); catalogued as COSV59467762; called by muse, mutect2, varscan2
- B3GNT8 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54198707, COSV99524685; called by muse, mutect2, varscan2
- BAZ1A | c.4094A>G p.N1365S | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV62411497; called by muse, mutect2, varscan2
- BRWD1 | c.5614G>C p.D1872H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV60899499; called by muse, mutect2, varscan2
- BRWD3 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV64751588; called by muse, mutect2, varscan2
- C1S | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as COSV61071811; called by muse, mutect2
- C6 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54714186, COSV54714253; called by muse, mutect2
- CAMTA2 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61836791; called by muse, mutect2, varscan2
- CARD6 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54567797; called by muse, mutect2
- CBLB | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.129); catalogued as COSV51432523; called by muse, mutect2, varscan2
- CCDC170 | c.1342A>T p.M448L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV53343886; called by muse, mutect2, varscan2
- CD244 | c.559G>C p.E187Q (on ENST00000368033 / NM_001166663.2; = p.E182Q on NM_016382.4) | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.134); catalogued as COSV100458709, COSV59236985, COSV59239951; called by muse, mutect2
- CDH18 | c.2008G>T p.A670S | Missense Mutation (SNP) | VAF 211/387 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1429028697, COSV56944510; called by muse, mutect2, varscan2
- CDH19 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50968321; called by muse, mutect2, varscan2
- CECR2 | c.2706C>A p.S902R (on ENST00000342247 / NM_001290047.2; = p.S719R on NM_001290046.1) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1268190307, COSV52845288; called by muse, mutect2
- CENPE | c.4780G>A p.E1594K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV54385771; called by muse, mutect2, varscan2
- CIT | c.2429C>G p.S810C | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55877208; called by muse, mutect2, varscan2
- CNTN6 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs865997842, COSV63181952; called by muse, mutect2, varscan2
- COL14A1 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52862423; called by muse, mutect2, varscan2
- CSMD3 | c.4342G>A p.D1448N (on ENST00000297405 / NM_001363185.1; = p.D1344N on NM_052900.3) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV52090534, COSV52257724, COSV52306319; called by muse, mutect2, varscan2
- DAAM2 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV51372169; called by muse, mutect2
- DCC | c.2746T>C p.Y916H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59120731; called by muse, mutect2, varscan2
- DDX43 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1178850066, COSV64813370; called by muse, mutect2, varscan2
- DGKD | c.2610G>T p.K870N (on ENST00000264057 / NM_152879.3; = p.K826N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51076252; called by muse, mutect2, varscan2
- DOP1B | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs775847530, COSV67694715; called by muse, mutect2, varscan2
- DPYS | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV60911503; called by muse, mutect2, varscan2
- DTL | c.1662G>C p.R554S | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65342895; called by muse, mutect2
- DYNC2H1 | c.9066G>C p.R3022S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV62101044; called by muse, mutect2
- ELAC2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs1247875701, COSV62033564; called by muse, mutect2, varscan2
- EVC | c.707T>A p.F236Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53836000; called by muse, mutect2, varscan2
- EXO1 | c.2084G>A p.C695Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV62218800; called by muse, mutect2, varscan2
- FAM166A | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV100457761, COSV61118205; called by mutect2, varscan2
- FAXDC2 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1386811208, COSV58173409; called by muse, mutect2
- FBXO34 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV58253430, COSV58255950; called by muse, mutect2, varscan2
- FRYL | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1243340001, COSV51955102; called by muse, mutect2, varscan2
- FZD7 | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.074); catalogued as rs768936211, COSV53810911; called by muse, mutect2, varscan2
- GJA1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 30/211 reads (14%) | catalogued as COSV56998819; called by muse, mutect2, varscan2
- GRIA1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53615094; called by muse, mutect2, varscan2
- GRID2 | c.1499A>C p.Q500P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.754); catalogued as COSV56237529; called by muse, mutect2, varscan2
- GRM3 | c.2560T>G p.S854A | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV64471593, COSV64476468; called by muse, mutect2, varscan2
- GSDME | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.17); catalogued as COSV61652493; called by muse, mutect2
- H2AC11 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60362432; called by muse, mutect2, varscan2
- HAUS6 | c.1529C>G p.S510* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV65840451; called by muse, mutect2
- HLA-A | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs199474481, COSV65138007; called by muse, mutect2
- INO80 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62740675; called by mutect2, varscan2
- JMJD1C | c.3662A>T p.E1221V | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59516972; called by muse, mutect2, varscan2
- JMJD1C | c.3661G>T p.E1221* | Nonsense Mutation (SNP) | VAF 17/163 reads (10%) | catalogued as COSV59516978; called by muse, mutect2, varscan2
- KCNH8 | c.1417A>T p.I473L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs779247147, COSV60471126; called by muse, mutect2, varscan2
- KDM5A | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV66994844; called by muse, mutect2, varscan2
- KIAA1109 | c.4800A>T p.L1600F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as COSV52684898; called by muse, mutect2, varscan2
- KMT2E | c.4730C>T p.S1577F | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as COSV57569298, COSV57577125; called by muse, mutect2, varscan2
- KRTAP19-5 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV61859283; called by muse, mutect2, varscan2
- LARP4B | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV60222690; called by muse, mutect2, varscan2
- LGR4 | c.1969A>C p.N657H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.273); catalogued as COSV60821323, COSV60821675; called by muse, mutect2, varscan2
- LHFPL1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV64333831; called by muse, mutect2, varscan2
- LIPH | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56185154; called by muse, mutect2, varscan2
- MACF1 | c.9058A>G p.S3020G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV57133716; called by muse, mutect2, varscan2
- MACF1 | c.12055G>A p.E4019K (on ENST00000372915; = p.E1952K on NM_012090.5) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV57133725; called by muse, mutect2, varscan2
- MAMDC4 | c.2207T>A p.I736N (on ENST00000445819; = p.I657N on NM_206920.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58072878; called by muse, mutect2, varscan2
- MARCHF10 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV60889429; called by muse, mutect2, varscan2
- MBNL2 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV59123782; called by muse, mutect2, varscan2
- MGAT3 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs149871838; called by muse, mutect2
- MKLN1 | c.1381A>T p.M461L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV61762025; called by muse, mutect2, varscan2
- MRGPRX1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762813146, COSV57108777; called by muse, mutect2
- MS4A6A | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs750186088, COSV60620638, COSV60620712; called by muse, mutect2, varscan2
- MX2 | c.1971T>A p.N657K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.491); catalogued as COSV58098120; called by muse, mutect2, varscan2
- MYCBP2 | c.188+1G>A p.X63_splice (on ENST00000357337; = p.X101_splice on NM_015057.5) | Splice Site (SNP) | VAF 5/48 reads (10%) | catalogued as rs753513375, COSV62031028; called by mutect2, varscan2
- MYT1 | c.2281G>C p.D761H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60510309; called by muse, mutect2
- NBEA | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.847); catalogued as COSV59806242; called by muse, mutect2
- NFATC2IP | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs761180637, COSV57910165, COSV57910872, COSV57910897; called by mutect2, varscan2
- NFIB | c.31-2A>G p.X11_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV66621148; called by muse, mutect2, varscan2
- NFXL1 | c.2220G>C p.K740N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV61199985; called by muse, mutect2, varscan2
- NLRP8 | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs1260849807, COSV52591228, COSV52595320; called by muse, mutect2, varscan2
- OR2M3 | c.619A>C p.I207L | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142664129; called by muse, mutect2, varscan2
- OR2M7 | c.797A>C p.H266P | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs769301368, COSV58739963; called by muse, mutect2, varscan2
- OR4D10 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV73260157; called by muse, mutect2, varscan2
- OR6C76 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV60389527; called by muse, mutect2, varscan2
- PACRGL | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 9/143 reads (6%) | catalogued as COSV54844006; called by muse, mutect2
- PBRM1 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV56291562; called by muse, mutect2, varscan2
- PBX1 | c.1038G>T p.L346F | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.288); catalogued as rs1324292200, COSV63346299; called by muse, mutect2
- PCDHGA8 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV53995489; called by muse, mutect2, varscan2
- PDCD2 | c.297A>C p.Q99H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV51341381; called by muse, mutect2, varscan2
- PISD | c.1039G>A p.G347S (on ENST00000439502 / NM_001326412.1; = p.G313S on NM_014338.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs760346623, COSV56716453, COSV56718329; called by muse, mutect2, varscan2
- PLEKHA6 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV55337655; called by muse, mutect2
- PLPPR5 | c.881T>C p.M294T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs143279943; called by muse, mutect2, varscan2
- PLRG1 | c.404+2T>A p.X135_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | catalogued as COSV57424311; called by muse, mutect2, varscan2
- POLQ | c.6128G>T p.R2043L | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51757540; called by muse, mutect2, varscan2
- PPP2R1A | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV59046761; called by muse, mutect2
- PSMD1 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1197507261, COSV58081499; called by muse, mutect2, varscan2
- PXDNL | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62487762, COSV62501020; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3413G>C p.R1138T | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV54762403, COSV54764859; called by muse, mutect2, varscan2
- RACGAP1 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | catalogued as rs752168418, COSV56699038; called by muse, mutect2, varscan2
- RANBP6 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52390699; called by muse, mutect2, varscan2
- RASAL2 | c.2833C>G p.Q945E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV62718809; called by muse, mutect2, varscan2
- REC114 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58523838; called by muse, mutect2, varscan2
- RSC1A1 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); catalogued as COSV60780599; called by muse, mutect2, varscan2
- RTTN | c.6059A>G p.Q2020R | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.463); catalogued as rs200829574, COSV55348975; called by muse, mutect2, varscan2
- RTTN | c.4448A>T p.H1483L | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55348981; called by muse, mutect2, varscan2
- SCN3B | c.21G>T p.L7F | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV54798582, COSV54800471; called by muse, mutect2, varscan2
- SDK1 | c.5489G>A p.G1830D | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745305864, COSV67369654; called by muse, mutect2
- SF3B2 | c.2429C>T p.T810M | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs372951764; called by muse, mutect2, varscan2
- SLC16A9 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as rs749448585, COSV68099901; called by muse, mutect2, varscan2
- SLC24A2 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53870715; called by muse, mutect2, varscan2
- SLC27A2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754606073, COSV51060992; called by muse, mutect2
- SLC34A2 | c.1593C>G p.F531L | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65942451; called by muse, mutect2, varscan2
- SLC9A3 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53803399; called by muse, mutect2
- SMG7 | c.1261T>A p.L421I | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61633035; called by muse, mutect2, varscan2
- SNX7 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.775); catalogued as COSV60268192, COSV60272154; called by muse, mutect2
- SPG11 | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV55999415; called by muse, mutect2, varscan2
- STAG1 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV52617751; called by muse, mutect2
- TBC1D21 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55996125; called by muse, mutect2, varscan2
- TBC1D9 | c.3526G>A p.D1176N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.136); catalogued as rs1332375592, COSV71308152; called by muse, mutect2
- TCEAL3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV54581113; called by muse, mutect2, varscan2
- TCTN1 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV66542004; called by muse, mutect2, varscan2
- TECRL | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101168525, COSV67086765, COSV67089147; called by muse, mutect2, varscan2
- TEKT3 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV58628761; called by muse, mutect2, varscan2
- TEX44 | c.1073C>G p.T358S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV58355229; called by muse, mutect2, varscan2
- TFB1M | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV65699645; called by muse, mutect2, varscan2
- THUMPD2 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV53188417; called by muse, mutect2
- TIGD7 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV51916486; called by muse, mutect2, varscan2
- TLN1 | c.4249G>A p.G1417R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1315216327, COSV59210053; called by mutect2, varscan2
- TM4SF4 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59516611; called by muse, mutect2, varscan2
- TMEM255A | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59030558; called by muse, mutect2
- TNRC6B | c.4340G>T p.G1447V (on ENST00000454349 / NM_001162501.2; = p.G1337V on NM_015088.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV57302586; called by muse, mutect2, varscan2
- TOR1AIP2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.918); catalogued as COSV62626716; called by muse, mutect2, varscan2
- TTN | c.18184C>A p.L6062I (on ENST00000591111; = p.L5135I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | PolyPhen probably damaging (0.996); catalogued as COSV60174967, COSV60219261; called by muse, mutect2, varscan2
- TYK2 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53389782; called by muse, mutect2, varscan2
- UBOX5 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1435788212, COSV53907898; called by muse, mutect2, varscan2
- UGT2B4 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59318985; called by muse, mutect2, varscan2
- USF3 | c.3653G>A p.G1218E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV57075536; called by muse, mutect2, varscan2
- USP9X | c.6565+2T>A p.X2189_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV61072703; called by muse, mutect2, varscan2
- VIL1 | c.995T>G p.V332G | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50292685; called by muse, mutect2
- VIPR2 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51112806; called by muse, mutect2, varscan2
- VTA1 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.574); catalogued as COSV62659861; called by muse, mutect2, varscan2
- VWA3B | c.1382G>A p.S461N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV68245033; called by muse, mutect2
- WWC1 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV54655389; called by muse, mutect2, varscan2
- XPO1 | c.3157C>G p.Q1053E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.036); catalogued as COSV68946983; called by muse, mutect2, varscan2
- ZMAT4 | c.229T>A p.C77S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52707914; called by muse, mutect2, varscan2
- ZNF221 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV52110451; called by muse, mutect2, varscan2
- ZNF280A | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | catalogued as COSV57481551; called by muse, mutect2, varscan2
- ZNF529 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs777934586, COSV61901355; called by muse, mutect2, varscan2
- ZNF567 | c.952T>C p.F318L (on ENST00000536254 / NM_001322913.1; = p.F287L on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62446071; called by muse, mutect2, varscan2
- ZNF607 | c.1422G>C p.E474D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV62205942; called by muse, mutect2, varscan2
- ZXDA | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs370655010, COSV62388459; called by muse, mutect2, varscan2
- BAZ2A | c.5510C>T p.P1837L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUL7 | c.4153del p.A1385Qfs*24 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- FCGBP | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- MCRS1 | c.1352_1362del p.L451Rfs*51 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel
- MYCBP2 | c.5826del p.V1943Lfs*4 (on ENST00000357337; = p.V1981Lfs*4 on NM_015057.5) | Frame Shift Del (DEL) | VAF 27/119 reads (23%) | called by mutect2, pindel, varscan2
- PCLO | c.14867A>C p.Y4956S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ADGRB3 | c.2784A>T p.I928= | Silent (SNP) | VAF 33/195 reads (17%) | catalogued as COSV53254071; called by muse, mutect2, varscan2
- AIRE | c.807T>C p.G269= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1312909039, COSV52395749; called by muse, mutect2, varscan2
- API5 | c.1110C>G p.L370= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV66634229; called by muse, mutect2, varscan2
- ATP10B | c.1911C>T p.F637= | Silent (SNP) | VAF 22/211 reads (10%) | catalogued as rs1001099550, COSV100515388, COSV59159618; called by muse, mutect2, varscan2
- CAPN13 | c.96C>A p.G32= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54433209; called by muse, mutect2
- CELSR2 | c.4926C>G p.L1642= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV54776423, COSV99602826; called by muse, mutect2, varscan2
- CHRDL1 | c.663G>A p.G221= (on ENST00000372045; = p.G227= on NM_145234.4) | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as COSV54327150; called by muse, mutect2, varscan2
- DLGAP3 | c.2598G>A p.V866= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV52396054; called by muse, mutect2, varscan2
- DMD | c.8619G>T p.L2873= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100629655, COSV58933115; called by muse, mutect2, varscan2
- DPY19L2 | c.1197T>G p.S399= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV60544907; called by muse, mutect2
- DSCAM | c.5841G>A p.P1947= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs754261783, COSV68021904; called by muse, mutect2, varscan2
- DYNC1H1 | c.10383C>T p.I3461= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV64139868; called by muse, mutect2, varscan2
- DZIP1 | c.513G>A p.K171= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV61268003; called by muse, mutect2
- ECE1 | c.1338G>T p.A446= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV51668245; called by muse, mutect2, varscan2
- EGR4 | c.798T>C p.P266= (on ENST00000545030; = p.P163= on NM_001965.4) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV71532231; called by muse, mutect2, varscan2
- FGD1 | c.2610C>T p.L870= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV64309255; called by muse, mutect2, varscan2
- GPR173 | c.891C>A p.L297= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV60237370; called by muse, mutect2, varscan2
- GUCY2F | c.48G>A p.A16= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV54306037; called by muse, mutect2, varscan2
- KALRN | c.2436G>A p.Q812= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV53774257; called by muse, mutect2, varscan2
- KCNAB1 | c.852C>A p.L284= (on ENST00000490337 / NM_172160.3; = p.L273= on NM_003471.3) | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV56750228; called by muse, mutect2, varscan2
- LAMA2 | c.1755C>T p.S585= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV70343801; called by muse, mutect2, varscan2
- MAGEC3 | c.1713G>T p.V571= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as COSV53581546, COSV68924053; called by muse, mutect2, varscan2
- MAGT1 | c.60C>A p.I20= (on ENST00000618282 / NM_001367916.1; = p.I52= on NM_032121.5) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV63782550; called by muse, mutect2, varscan2
- MARK3 | c.1569G>A p.Q523= | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as COSV53513809; called by muse, mutect2, varscan2
- MYCBP2 | c.8688A>G p.E2896= (on ENST00000357337; = p.E2934= on NM_015057.5) | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV62031003; called by muse, mutect2
- MYH11 | c.1330C>T p.L444= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as COSV55562873; called by muse, mutect2, varscan2
- NPY5R | c.81C>T p.F27= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV58452473; called by muse, mutect2
- OR52B2 | c.741C>T p.L247= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV73209496; called by muse, mutect2, varscan2
- OR8H2 | c.390A>G p.L130= | Silent (SNP) | VAF 28/237 reads (12%) | catalogued as COSV57946554; called by muse, mutect2, varscan2
- PATJ | c.1953C>A p.R651= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as COSV57167596; called by muse, mutect2, varscan2
- PEG3 | c.4329C>G p.A1443= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV55624172, COSV55640348, COSV55641484; called by muse, mutect2, varscan2
- PIGS | c.453C>T p.S151= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV52025715; called by muse, mutect2, varscan2
- PNPLA2 | c.561C>T p.F187= | Silent (SNP) | VAF 11/167 reads (7%) | catalogued as COSV60744836; called by muse, mutect2
- PTPRO | c.405A>C p.T135= | Silent (SNP) | VAF 27/229 reads (12%) | catalogued as COSV55517194; called by muse, mutect2, varscan2
- RESF1 | c.3153A>T p.L1051= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV57024232; called by muse, mutect2, varscan2
- RIOK3 | c.1365C>G p.V455= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV59774229; called by muse, mutect2, varscan2
- RPL10 | c.243C>T p.G81= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV50010801; called by muse, mutect2, varscan2
- SLC18A1 | c.1140G>A p.L380= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1221478754, COSV52349841; called by muse, mutect2, varscan2
- STK35 | c.783C>T p.V261= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV55692064; called by muse, mutect2, varscan2
- STON1 | c.978A>T p.P326= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV59134731, COSV59139222; called by muse, mutect2, varscan2
- SYNE1 | c.3897G>A p.A1299= (on ENST00000367255 / NM_182961.4; = p.A1306= on NM_033071.3) | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV55034127; called by muse, mutect2, varscan2
- TBX20 | c.624C>T p.L208= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV68784814; called by muse, mutect2, varscan2
- TLR2 | c.876T>C p.V292= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV52607406; called by muse, mutect2, varscan2
- TMOD4 | c.318A>G p.A106= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as COSV54861575; called by muse, mutect2, varscan2
- TNXB | c.9726G>A p.V3242= (on ENST00000647633; = p.V2995= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV64484261; called by muse, mutect2, varscan2
- TTC36 | c.28C>T p.L10= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as COSV57097402; called by muse, mutect2, varscan2
- TTN | c.15351C>A p.S5117= (on ENST00000591111; = p.S4190= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV60219273; called by muse, mutect2, varscan2
- TYW1 | c.1308G>A p.R436= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs1394890735, COSV62754439; called by muse, mutect2, varscan2
- UBR4 | c.10050C>T p.A3350= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs534688684, COSV64395163; called by muse, mutect2, varscan2
- UGT2B28 | c.1290G>A p.K430= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV59433451; called by muse, mutect2, varscan2
- USP25 | c.2214A>C p.P738= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV53487724; called by muse, mutect2, varscan2
- VPS35L | c.657A>G p.S219= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV51987706; called by muse, mutect2, varscan2
- WNK4 | c.987C>T p.R329= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs1186004572, COSV53821599; called by muse, mutect2, varscan2
- ZFYVE26 | c.753G>C p.G251= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV61331547; called by muse, mutect2, varscan2
- ZXDA | c.1884C>A p.I628= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100699380; called by mutect2, varscan2
- AL353804.4 | chrX:73823588 T>C | 5'Flank (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2
- CEP295 | chr11:93731084 G>C | 3'Flank (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- PRR12 | c.52-299C>T | Intron (SNP) | VAF 3/31 reads (10%) | catalogued as COSV69819006; called by muse, mutect2
- PRSS3 | c.-197C>G | 5'UTR (SNP) | VAF 11/362 reads (3%) | catalogued as COSV61557988; called by muse, mutect2
- RBPMS | c.528+2738C>G | Intron (SNP) | VAF 25/157 reads (16%) | catalogued as COSV99823994; called by muse, mutect2, varscan2
- THRB | c.284-12849C>T | Intron (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99769511; called by muse, mutect2, varscan2
- Unknown | chr21:16071250 T>C | IGR (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
